Somatic mutation profile of tumor specimen TCGA-P3-A6T6-01A (aliquot TCGA-P3-A6T6-01A-11D-A34J-08) from TCGA case TCGA-P3-A6T6, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower gum; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 53.9 years (19,694 days).
Specimen TCGA-P3-A6T6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a0f91a9-b934-4d81-8286-3c069d64bce9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P3-A6T6-10A (Blood Derived Normal), aliquot TCGA-P3-A6T6-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49e58dce-c95d-434b-9289-30b5fb55033e

The open-access MAF lists 136 somatic variants for this specimen: 100 protein-altering or splice-affecting, 29 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 29, Nonsense Mutation 8, Splice Site 5, 3'UTR 3, Intron 3, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.728G>C p.R243T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV100856824; called by muse, mutect2, varscan2
- ADHFE1 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as COSV99397869; called by muse, mutect2, varscan2
- ANKRD27 | c.2746A>G p.T916A | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV100042838; called by muse, mutect2, varscan2
- ARHGAP24 | c.1644G>C p.Q548H (on ENST00000395184 / NM_001025616.3; = p.Q455H on NM_031305.3) | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1428421696, COSV99982097; called by muse, mutect2, varscan2
- ARHGAP5 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.995); catalogued as COSV100565415; called by muse, mutect2, varscan2
- ARMC4 | c.1691A>T p.K564M | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100536881; called by muse, mutect2, varscan2
- ARSI | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs755465506, COSV100155986; called by muse, mutect2, varscan2
- CACNA1B | c.5100G>C p.L1700F | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99497658; called by muse, mutect2, varscan2
- CACNA1D | c.1527C>A p.N509K (on ENST00000350061 / NM_001128840.3; = p.N529K on NM_000720.4) | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV99858297; called by muse, mutect2, varscan2
- CDKAL1 | c.944A>C p.Y315S | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99215480; called by muse, mutect2, varscan2
- CHST2 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100535973; called by muse, mutect2, varscan2
- COL11A1 | c.4192C>T p.Q1398* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV100616652; called by muse, mutect2, varscan2
- COL11A1 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV62193640; called by muse, mutect2, varscan2
- COL16A1 | c.3417G>T p.E1139D | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.935); catalogued as COSV99594538; called by muse, mutect2, varscan2
- CRISP1 | c.103A>T p.T35S | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100236902; called by muse, varscan2
- CTNNA1 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV100242787; called by muse, mutect2, varscan2
- CWF19L2 | c.2147T>A p.L716* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV99979064; called by muse, mutect2, varscan2
- DMKN | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV100303617; called by muse, mutect2, varscan2
- DMXL2 | c.5983G>C p.G1995R | Missense Mutation (SNP) | VAF 24/287 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.911); catalogued as COSV99196404; called by muse, mutect2
- DNAJC17 | c.445C>G p.Q149E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.178); catalogued as COSV99591688; called by muse, mutect2, varscan2
- DUOXA1 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99973232; called by muse, mutect2, varscan2
- DZIP1 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.498); catalogued as COSV100714097; called by muse, mutect2, varscan2
- E2F5 | c.1011T>G p.D337E | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99809548; called by muse, mutect2, varscan2
- EPS8L3 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100719717; called by muse, mutect2, varscan2
- EXOG | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs767049492, COSV99815304; called by muse, mutect2, varscan2
- FLAD1 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs539158486, COSV99422539; called by muse, mutect2, varscan2
- FOXC2 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs751774927, CD098486, COSV57444109; called by muse, mutect2, varscan2
- FRY | c.4592G>A p.G1531E | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100969314; called by muse, mutect2, varscan2
- GABARAPL2 | c.119A>C p.Q40P | Missense Mutation (SNP) | VAF 83/196 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99231147; called by muse, mutect2, varscan2
- GET1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV61555184; called by muse, mutect2
- GIMAP6 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 115/262 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs372777404, COSV61033706; called by muse, mutect2, varscan2
- GJC1 | c.899A>T p.Q300L | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100395181; called by muse, mutect2, varscan2
- GOLGA6B | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 28/290 reads (10%) | catalogued as rs753064173, COSV101406922; called by muse, mutect2
- GPNMB | c.1055G>C p.G352A (on ENST00000381990 / NM_001005340.2; = p.G340A on NM_002510.3) | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99326501; called by muse, mutect2, varscan2
- GPR107 | c.940-1G>A p.X314_splice | Splice Site (SNP) | VAF 69/187 reads (37%) | catalogued as COSV61279099; called by muse, mutect2, varscan2
- GPX6 | c.263A>T p.E88V | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100724842; called by muse, mutect2, varscan2
- GSG1 | c.226G>T p.V76L (on ENST00000651961 / NM_001080555.4; = p.V63L on NM_031289.5) | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100189271; called by muse, mutect2, varscan2
- HEATR5B | c.5126A>T p.K1709I | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99249373; called by muse, mutect2, varscan2
- HIF3A | c.70C>T p.R24C (on ENST00000377670 / NM_152795.4; = p.P3= on NM_022462.4) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52199157, COSV99355790; called by muse, mutect2, varscan2
- IL12RB2 | c.1978C>T p.Q660* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as COSV99255101; called by muse, mutect2, varscan2
- IPO8 | c.1045-1G>C p.X349_splice | Splice Site (SNP) | VAF 27/63 reads (43%) | catalogued as COSV99805356; called by muse, mutect2, varscan2
- ITLN1 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100406238, COSV100406359; called by muse, mutect2, varscan2
- ITLN2 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs368090480, COSV63538141; called by muse, mutect2, varscan2
- KCNH1 | c.944T>A p.V315E | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.506); catalogued as COSV99659375; called by muse, mutect2, varscan2
- KCNK10 | c.733A>T p.I245F | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV100068388; called by muse, mutect2, varscan2
- KNTC1 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100338359; called by muse, mutect2, varscan2
- LRIG2 | c.1645G>T p.V549F | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV100743376; called by muse, mutect2, varscan2
- LRRC6 | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 67/113 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs746914801, COSV51543844; called by muse, mutect2, varscan2
- LSG1 | c.226+1G>A p.X76_splice | Splice Site (SNP) | VAF 41/170 reads (24%) | catalogued as rs756428541, COSV99503248; called by muse, mutect2, varscan2
- MAP7D1 | c.1468C>G p.L490V | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.978); catalogued as COSV100294522; called by muse, mutect2, varscan2
- MED15 | c.1412C>T p.S471F (on ENST00000263205 / NM_001003891.3; = p.S431F on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99487384, COSV99487719; called by muse, mutect2, varscan2
- MEGF8 | c.6847G>A p.E2283K (on ENST00000251268 / NM_001271938.2; = p.E2216K on NM_001410.3) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV52104530; called by muse, mutect2, varscan2
- MEX3B | c.361G>C p.A121P | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100314048; called by muse, mutect2, varscan2
- MIOS | c.2197-1G>C p.X733_splice | Splice Site (SNP) | VAF 47/103 reads (46%) | catalogued as COSV100402790; called by muse, mutect2, varscan2
- NCK1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.102); catalogued as COSV99999578; called by muse, mutect2, varscan2
- NLRP14 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 73/125 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV100205023; called by muse, mutect2, varscan2
- NMT2 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV100975551; called by muse, mutect2, varscan2
- NPHS1 | c.1655C>A p.A552D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as CM158441, COSV100799900; called by muse, mutect2, varscan2
- NSD1 | c.4546G>T p.E1516* | Nonsense Mutation (SNP) | VAF 22/35 reads (63%) | catalogued as COSV100729144; called by muse, mutect2, varscan2
- NSMAF | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs561860265, COSV99232913; called by muse, mutect2
- OR4D10 | c.433A>G p.T145A | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101597014; called by muse, mutect2, varscan2
- OR6C6 | c.328T>A p.F110I | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as rs1235572146, COSV100626475; called by muse, mutect2, varscan2
- OTUD5 | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs926134865, COSV50233804, COSV50240660, COSV99331981; called by muse, mutect2, varscan2
- PCBP1 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as COSV57851758; called by muse, mutect2, varscan2
- PCIF1 | c.92C>G p.P31R | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100976064, COSV100976111; called by muse, mutect2, varscan2
- PDS5B | c.3298C>A p.Q1100K | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV100220988; called by muse, mutect2, varscan2
- PLA2G4E | c.490A>C p.K164Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV101268576; called by muse, mutect2, varscan2
- PLEKHA6 | c.2252T>G p.V751G | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV99692122; called by muse, mutect2, varscan2
- PPFIA3 | c.2582G>A p.C861Y | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100494945; called by muse, mutect2, varscan2
- PPP2R5E | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.494); catalogued as COSV100518624; called by muse, mutect2, varscan2
- RASGRF1 | c.3681G>T p.E1227D | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV101174522; called by muse, mutect2, varscan2
- RASSF4 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.725); catalogued as rs747054187, COSV100436988; called by muse, mutect2, varscan2
- REG1B | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.443); catalogued as COSV59305706; called by muse, mutect2, varscan2
- RHBDF1 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV99244730; called by muse, mutect2, varscan2
- RIPK2 | c.400T>C p.Y134H | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99609896; called by muse, mutect2, varscan2
- RNASE13 | c.405C>G p.Y135* | Nonsense Mutation (SNP) | VAF 66/195 reads (34%) | catalogued as COSV100409567; called by muse, mutect2, varscan2
- SBNO1 | c.3427G>T p.D1143Y (on ENST00000420886; = p.D1142Y on NM_018183.5) | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99929245; called by muse, mutect2, varscan2
- SCN11A | c.2090C>G p.S697C | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100181641; called by muse, mutect2, varscan2
- SCNN1B | c.386C>G p.P129R | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.906); catalogued as COSV100225685; called by muse, mutect2, varscan2
- SDK2 | c.1522A>G p.I508V | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV101167689; called by muse, mutect2, varscan2
- SLC22A11 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as COSV100102351; called by muse, varscan2
- SLC6A2 | c.1016G>T p.C339F | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99573899; called by muse, mutect2, varscan2
- SLK | c.2558A>T p.Q853L | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV100211775; called by muse, mutect2
- SMG7 | c.1957G>T p.G653* | Nonsense Mutation (SNP) | VAF 80/124 reads (65%) | catalogued as COSV100750321; called by muse, mutect2, varscan2
- SSH1 | c.2271G>C p.L757F | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.216); catalogued as COSV100425554; called by muse, mutect2, varscan2
- STH | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as COSV99290546; called by muse, mutect2, varscan2
- SYT6 | c.746G>T p.R249L (on ENST00000610222 / NM_001366225.1; = p.R164L on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs139165674, COSV101059648; called by muse, mutect2, varscan2
- TMEM161A | c.200G>C p.G67A | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.712); catalogued as COSV50777971, COSV99365499; called by muse, mutect2, varscan2
- TNRC6A | c.5479G>C p.E1827Q | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100170043; called by muse, mutect2, varscan2
- TOGARAM1 | c.2750C>G p.P917R | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV100818053; called by muse, mutect2, varscan2
- TOGARAM2 | c.3049C>T p.Q1017* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV101091137; called by muse, mutect2, varscan2
- TSPEAR | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); catalogued as rs782644109, COSV59976402; called by muse, mutect2, varscan2
- TTC21A | c.1487A>G p.K496R | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100087332; called by muse, mutect2
- UGT2B15 | c.1080G>C p.Q360H | Missense Mutation (SNP) | VAF 107/340 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100592327; called by muse, mutect2, varscan2
- VWA8 | c.4155G>T p.W1385C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV101022679, COSV101022953; called by muse, mutect2, varscan2
- YY1AP1 | c.2152T>C p.F718L (on ENST00000295566 / NM_139118.2; = p.F661L on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.68); catalogued as COSV99804139; called by muse, mutect2, varscan2
- ZNF43 | c.308G>C p.R103T | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100731825, COSV61685676; called by muse, mutect2, varscan2
- CARD11 | c.2837_2839+1del p.X946_splice | Splice Site (DEL) | VAF 28/78 reads (36%) | called by mutect2, pindel, varscan2
- DHX29 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.454); called by muse, mutect2
- NDUFS5 | c.288_292del p.H98Wfs*? | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- AADAC | c.951G>C p.V317= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs1019038147, COSV99233242; called by muse, mutect2, varscan2
- ADGRL1 | c.1008C>T p.D336= (on ENST00000340736 / NM_001008701.3; = p.D331= on NM_014921.5) | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100529549; called by muse, mutect2, varscan2
- AMER2 | c.186G>A p.K62= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs1259715708, COSV100766265; called by muse, mutect2, varscan2
- C8orf33 | c.66G>T p.A22= | Silent (SNP) | VAF 90/129 reads (70%) | catalogued as COSV100510538; called by muse, mutect2, varscan2
- CDKAL1 | c.945C>T p.Y315= | Silent (SNP) | VAF 55/202 reads (27%) | catalogued as rs368097465; called by muse, mutect2, varscan2
- CSMD2 | c.8058C>T p.S2686= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs769904635, COSV53883795; called by muse, mutect2, varscan2
- DIRAS2 | c.402C>T p.S134= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs76821927, COSV101005863; called by muse, mutect2, varscan2
- DNAH3 | c.1383T>G p.V461= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as COSV99767682; called by muse, mutect2, varscan2
- FUCA2 | c.762G>T p.R254= | Silent (SNP) | VAF 36/54 reads (67%) | catalogued as COSV99136077; called by muse, mutect2, varscan2
- GNRHR | c.129C>T p.F43= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs774375011, COSV99892174; called by muse, mutect2, varscan2
- GOLGA4 | c.5091A>T p.S1697= | Silent (SNP) | VAF 66/181 reads (36%) | catalogued as COSV100728917, COSV62710848; called by muse, mutect2, varscan2
- IFI27 | c.75C>T p.A25= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs1186947916, COSV100108390; called by muse, mutect2, varscan2
- IQGAP1 | c.4020G>A p.L1340= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99185022; called by muse, mutect2, varscan2
- KIF3C | c.975G>A p.L325= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV53101387, COSV99267403; called by muse, mutect2, varscan2
- LAMA1 | c.6048G>A p.T2016= | Silent (SNP) | VAF 26/149 reads (17%) | catalogued as rs545116059, COSV101055261; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRCH3 | c.1269A>G p.P423= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as COSV100605095; called by muse, mutect2, varscan2
- MBTPS1 | c.231G>T p.L77= | Silent (SNP) | VAF 49/134 reads (37%) | catalogued as COSV100597618; called by muse, mutect2, varscan2
- MTERF3 | c.456T>C p.H152= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as COSV99749799; called by muse, mutect2, varscan2
- PPP2R5D | c.774C>G p.L258= | Silent (SNP) | VAF 46/143 reads (32%) | catalogued as COSV55151491, COSV99776545; called by muse, mutect2, varscan2
- REC8 | c.1407G>A p.V469= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV100269052; called by muse, mutect2, varscan2
- SART3 | c.366C>T p.L122= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs746105160, COSV99934090; called by muse, mutect2, varscan2
- SFMBT2 | c.2169C>T p.D723= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs149003494; called by muse, mutect2, varscan2
- SIM2 | c.345C>G p.S115= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as COSV99293278; called by muse, mutect2, varscan2
- SLC22A11 | c.1143C>T p.F381= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as rs765674133, COSV100102353; called by muse, varscan2
- SYT4 | c.1239G>A p.R413= | Silent (SNP) | VAF 127/329 reads (39%) | catalogued as COSV99673858; called by muse, mutect2, varscan2
- TUBA4A | c.810C>A p.A270= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV99944796; called by muse, mutect2, varscan2
- VSIG2 | c.492G>C p.L164= | Silent (SNP) | VAF 50/87 reads (57%) | catalogued as COSV99423247; called by muse, mutect2, varscan2
- ZBBX | c.1392T>C p.S464= | Silent (SNP) | VAF 74/252 reads (29%) | catalogued as COSV100284073; called by muse, mutect2, varscan2
- ZBTB3 | c.270G>C p.L90= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as COSV67361860, COSV67361987; called by muse, mutect2, varscan2
- CDK13 | c.*6_*7insATACTGATTATCT | 3'UTR (INS) | VAF 19/78 reads (24%) | called by mutect2, pindel, varscan2
- FAS | c.*173C>A | 3'UTR (SNP) | VAF 23/107 reads (21%) | catalogued as COSV100570740, COSV100570782; called by muse, mutect2, varscan2
- HDAC8 | c.738-9928G>A | Intron (SNP) | VAF 17/79 reads (22%) | catalogued as COSV101003303; called by muse, mutect2, varscan2
- LEKR1 | c.*1366G>C | 3'UTR (SNP) | VAF 37/102 reads (36%) | catalogued as COSV100739018; called by muse, mutect2, varscan2
- PPM1B | chr2:44232328 C>G | 3'Flank (SNP) | VAF 34/114 reads (30%) | catalogued as COSV56767707, COSV56769422; called by muse, mutect2, varscan2
- RGS3 | c.3081-112G>A | Intron (SNP) | VAF 22/80 reads (28%) | catalogued as COSV100636735; called by muse, mutect2, varscan2
- UNC5D | c.104-4798C>A | Intron (SNP) | VAF 27/70 reads (39%) | catalogued as rs1174683778, COSV99775461, COSV99779590; called by muse, mutect2, varscan2
